Somatic mutation profile of tumor specimen MP2PRT-PASUWM-TMP1-A (aliquot MP2PRT-PASUWM-TMP1-A-1-0-D-A82L-36) from MP2PRT case MP2PRT-PASUWM, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.3 years (2,298 days).
Specimen MP2PRT-PASUWM-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ceb3b335-80ce-4b4b-9565-13b9823ee284.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASUWM-NM1-A (Blood Derived Cancer - Bone Marrow, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASUWM-NM1-A-1-0-D-A82L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/355eaf5b-fc9d-4555-9f9e-bcbe2f389358

The open-access MAF lists 16 somatic variants for this specimen: 12 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 3, Frame Shift Ins 2, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DOT1L | c.956G>A p.R319H | Missense Mutation (SNP) | VAF 34/434 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV67110023; called by muse, mutect2
- EN1 | c.899A>T p.E300V | Missense Mutation (SNP) | VAF 154/401 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.076); catalogued as rs1290778429; called by muse, mutect2, varscan2
- GLI3 | c.3065C>T p.P1022L | Missense Mutation (SNP) | VAF 357/815 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV101230266, COSV67885736; called by muse, mutect2, varscan2
- HTRA1 | c.1297G>A p.V433I | Missense Mutation (SNP) | VAF 64/235 reads (27%) | SIFT tolerated (0.46); PolyPhen benign (0.13); catalogued as rs751200867, COSV64563953; called by muse, varscan2
- IL4I1 | c.1487C>T p.S496L | Missense Mutation (SNP) | VAF 315/664 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99680428; called by muse, mutect2, varscan2
- KCNK1 | c.544G>A p.V182I | Missense Mutation (SNP) | VAF 250/680 reads (37%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as rs199630093, COSV64034520; called by muse, mutect2, varscan2
- RYR2 | c.13363G>A p.E4455K | Missense Mutation (SNP) | VAF 44/402 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV100767331; called by muse, mutect2
- TTC3 | c.2334dup p.E779Rfs*18 | Frame Shift Ins (INS) | VAF 58/190 reads (31%) | catalogued as rs756650873; called by mutect2, varscan2
- VWF | c.1721C>T p.P574L | Missense Mutation (SNP) | VAF 97/344 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV54616876; called by muse, mutect2, varscan2
- JAK2 | c.2651T>C p.L884P | Missense Mutation (SNP) | VAF 92/328 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NCK1 | c.1111_1112insCCCT p.Y371Sfs*29 | Frame Shift Ins (INS) | VAF 41/157 reads (26%) | called by mutect2, pindel, varscan2
- NOX4 | c.470C>T p.T157I | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.362); called by muse, mutect2, varscan2
- CHMP7 | c.730C>T p.L244= | Silent (SNP) | VAF 88/380 reads (23%) | called by muse, mutect2, varscan2
- HTR1E | c.84T>C p.T28= | Silent (SNP) | VAF 17/429 reads (4%) | called by muse, mutect2
- ZNF532 | c.897G>A p.P299= | Silent (SNP) | VAF 26/372 reads (7%) | catalogued as rs368482208; called by muse, mutect2
- TRAJ9 | chr14:22539072 ins GCC | 3'Flank (INS) | VAF 109/253 reads (43%) | called by mutect2, pindel, varscan2
